Somatic mutation profile of tumor specimen C3L-00907-02 (aliquot CPT0064380009) from CPTAC case C3L-00907, project CPTAC-3 (Kidney — Adenomas and Adenocarcinomas). Sex at birth: male; Vital status: Alive; Primary diagnosis: Renal cell carcinoma, NOS; Tissue or organ of origin: Kidney, NOS; AJCC pathologic stage: Stage I; Tumor grade: G2; Age at diagnosis: 55.8 years (20,369 days).
Specimen C3L-00907-02: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Kidney; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 6b5520e2-2b3e-4601-8061-c9c6f5f4f29e.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3L-00907-31 (Blood Derived Normal), aliquot CPT0065420002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/104d9e9e-34f1-443d-9f11-b8cd97b930c1

The open-access MAF lists 59 somatic variants for this specimen: 46 protein-altering or splice-affecting, 8 silent, 5 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 36, Silent 8, Intron 4, Splice Region 4, Splice Site 3, In Frame Del 1, 5'UTR 1, Frame Shift Del 1, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KDM5C | c.1439C>T p.P480L | Missense Mutation (SNP) | VAF 95/227 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1057518697, BM1323210, COSV100949576, COSV64762787; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- VHL | c.266T>C p.L89P | Missense Mutation (SNP) | VAF 149/482 reads (31%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.966); catalogued as rs5030807, CM941368, COSV56543066, COSV56543312, COSV56543561; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- ACSM4 | c.982G>A p.V328M | Missense Mutation (SNP) | VAF 46/228 reads (20%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.986); catalogued as rs752916520, COSV68067373, COSV68069242; called by muse, mutect2, varscan2
- ADCY4 | c.931-4C>T | Splice Region (SNP) | VAF 34/178 reads (19%) | catalogued as rs1258704765; called by muse, mutect2, varscan2
- FOXF1 | c.797C>T p.S266L | Missense Mutation (SNP) | VAF 36/145 reads (25%) | SIFT tolerated (0.08); PolyPhen benign (0.173); catalogued as rs1030195503; called by muse, mutect2, varscan2
- GRHPR | c.506C>T p.A169V | Missense Mutation (SNP) | VAF 109/484 reads (23%) | SIFT deleterious (0.03); PolyPhen benign (0.206); catalogued as rs952908719; called by muse, mutect2, varscan2
- MEFV | c.1760-5C>T | Splice Region (SNP) | VAF 107/468 reads (23%) | catalogued as rs1319612887; called by muse, mutect2
- MTG1 | c.769G>A p.G257S | Missense Mutation (SNP) | VAF 38/222 reads (17%) | SIFT tolerated (0.07); PolyPhen benign (0.202); catalogued as rs559297659, COSV100448997; called by muse, mutect2, varscan2
- OR1C1 | c.361G>C p.D121H | Missense Mutation (SNP) | VAF 41/188 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV101376249; called by muse, mutect2, varscan2
- PAK6 | c.-116C>T | Splice Region (SNP) | VAF 28/173 reads (16%) | catalogued as rs1460458488; called by muse, mutect2, varscan2
- PCDHA7 | c.1439G>A p.G480E | Missense Mutation (SNP) | VAF 152/817 reads (19%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0); catalogued as rs781943368; called by muse, mutect2, varscan2
- PPM1A | c.904G>A p.V302M | Missense Mutation (SNP) | VAF 38/193 reads (20%) | SIFT deleterious (0.05); PolyPhen benign (0.096); catalogued as rs865808535; called by muse, mutect2, varscan2
- PRM2 | c.34C>G p.R12G | Missense Mutation (SNP) | VAF 75/325 reads (23%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.003); catalogued as COSV99617703; called by muse, mutect2, varscan2
- REPIN1 | c.1379T>C p.V460A | Missense Mutation (SNP) | VAF 54/288 reads (19%) | SIFT tolerated (0.73); PolyPhen possibly damaging (0.649); catalogued as rs770215207; called by muse, mutect2, varscan2
- TRIM6-TRIM34 | c.2237G>C p.R746T | Missense Mutation (SNP) | VAF 46/206 reads (22%) | SIFT tolerated (0.07); PolyPhen benign (0.241); catalogued as rs780882235; called by muse, mutect2, varscan2
- ZNF491 | c.517T>A p.S173T | Missense Mutation (SNP) | VAF 25/123 reads (20%) | SIFT tolerated (0.31); PolyPhen benign (0.026); catalogued as rs1341675608; called by muse, mutect2, varscan2
- ZNF513 | c.1147A>G p.S383G | Missense Mutation (SNP) | VAF 23/73 reads (32%) | SIFT deleterious (0.01); PolyPhen benign (0.315); catalogued as COSV52008679; called by muse, mutect2, varscan2
- ABCC1 | c.1702T>A p.Y568N | Missense Mutation (SNP) | VAF 34/153 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.958); called by muse, mutect2, varscan2
- AMY2A | c.1121G>A p.G374E | Missense Mutation (SNP) | VAF 33/233 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); called by mutect2, varscan2
- BHMG1 | c.514G>A p.A172T | Missense Mutation (SNP) | VAF 50/172 reads (29%) | SIFT tolerated (0.26); PolyPhen benign (0.141); called by muse, mutect2, varscan2
- BLZF1 | c.238A>G p.R80G | Missense Mutation (SNP) | VAF 28/140 reads (20%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.998); called by muse, varscan2
- DST | c.825A>C p.E275D | Missense Mutation (SNP) | VAF 19/105 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- GLS | c.1492A>G p.M498V | Missense Mutation (SNP) | VAF 52/228 reads (23%) | SIFT tolerated (0.23); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- HEATR3 | c.1917G>A p.M639I | Missense Mutation (SNP) | VAF 31/110 reads (28%) | SIFT tolerated (0.43); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- HELLS | c.31G>A p.G11S | Missense Mutation (SNP) | VAF 82/315 reads (26%) | SIFT tolerated, low confidence (0.19); PolyPhen benign (0.24); called by muse, mutect2, varscan2
- HMCN2 | c.4541C>A p.P1514Q | Missense Mutation (SNP) | VAF 24/143 reads (17%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.488); called by muse, mutect2, varscan2
- IL10 | c.300C>G p.N100K | Missense Mutation (SNP) | VAF 70/306 reads (23%) | SIFT tolerated (0.32); PolyPhen benign (0.199); called by muse, mutect2, varscan2
- MAPK6 | c.566C>G p.S189C | Missense Mutation (SNP) | VAF 31/242 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- MEF2D | c.856-2dup p.X286_splice | Splice Site (INS) | VAF 37/254 reads (15%) | called by mutect2, pindel, varscan2
- MIOX | c.341-7_341-6insA | Splice Region (INS) | VAF 17/87 reads (20%) | called by mutect2, pindel, varscan2
- MTF2 | c.712_728+1del p.X238_splice | Splice Site (DEL) | VAF 22/152 reads (14%) | called by mutect2, pindel
- NRBP1 | c.1572_1574del p.T525del | In Frame Del (DEL) | VAF 14/81 reads (17%) | called by mutect2, pindel
- NUP214 | c.5596T>C p.S1866P | Missense Mutation (SNP) | VAF 8/28 reads (29%) | SIFT tolerated (0.47); PolyPhen benign (0.099); called by muse, mutect2
- OR1C1 | c.47G>T p.G16V | Missense Mutation (SNP) | VAF 21/136 reads (15%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.532); called by mutect2, varscan2
- PBRM1 | c.44_50del p.V15Gfs*28 | Frame Shift Del (DEL) | VAF 19/115 reads (17%) | called by pindel, varscan2
- PCYOX1 | c.773G>C p.C258S | Missense Mutation (SNP) | VAF 59/285 reads (21%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.936); called by muse, mutect2, varscan2
- PGAP6 | c.1743G>A p.M581I | Missense Mutation (SNP) | VAF 37/164 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- POGK | c.1643T>A p.L548Q | Missense Mutation (SNP) | VAF 31/161 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.917); called by muse, mutect2, varscan2
- PTPRJ | c.3875A>G p.N1292S | Missense Mutation (SNP) | VAF 23/112 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2
- SCGN | c.63G>A p.W21* | Nonsense Mutation (SNP) | VAF 36/200 reads (18%) | called by muse, mutect2, varscan2
- SKIV2L | c.2084G>T p.G695V | Missense Mutation (SNP) | VAF 11/231 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.944); called by muse, mutect2
- SRGAP3 | c.801+1del p.X267_splice | Splice Site (DEL) | VAF 74/274 reads (27%) | called by mutect2, pindel, varscan2
- TMEM108 | c.1328C>G p.T443R | Missense Mutation (SNP) | VAF 21/105 reads (20%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.605); called by muse, mutect2, varscan2
- TTC22 | c.172C>G p.Q58E | Missense Mutation (SNP) | VAF 18/397 reads (5%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2
- ZBTB49 | c.46C>A p.H16N | Missense Mutation (SNP) | VAF 67/225 reads (30%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.503); called by muse, mutect2, varscan2
- ZNF281 | c.487C>G p.L163V | Missense Mutation (SNP) | VAF 85/467 reads (18%) | SIFT tolerated (0.2); PolyPhen benign (0.024); called by muse, mutect2, varscan2
- BORA | c.118T>C p.L40= | Silent (SNP) | VAF 47/234 reads (20%) | called by muse, mutect2, varscan2
- CRIM1 | c.1773G>A p.K591= | Silent (SNP) | VAF 16/59 reads (27%) | catalogued as rs756989756; called by muse, mutect2, varscan2
- ECHDC3 | c.474T>G p.V158= | Silent (SNP) | VAF 78/328 reads (24%) | called by muse, mutect2, varscan2
- HAS1 | c.129G>C p.G43= | Silent (SNP) | VAF 84/459 reads (18%) | catalogued as rs975588969; called by muse, mutect2, varscan2
- JMJD1C | c.4197C>A p.I1399= | Silent (SNP) | VAF 46/194 reads (24%) | called by muse, mutect2, varscan2
- LENG8 | c.654C>T p.G218= | Silent (SNP) | VAF 32/163 reads (20%) | called by muse, varscan2
- LUC7L | c.57G>A p.R19= | Silent (SNP) | VAF 26/175 reads (15%) | catalogued as rs972994693; called by muse, mutect2, varscan2
- RHPN1 | c.1915C>A p.R639= | Silent (SNP) | VAF 84/374 reads (22%) | catalogued as rs374961930; called by muse, mutect2, varscan2
- ARIH1 | c.912-26T>G | Intron (SNP) | VAF 34/126 reads (27%) | called by muse, mutect2, varscan2
- KIF1B | c.2115+6209A>C | Intron (SNP) | VAF 140/632 reads (22%) | called by muse, mutect2, varscan2
- RSAD1 | c.474+91_474+94del | Intron (DEL) | VAF 13/71 reads (18%) | catalogued as rs765772428; called by pindel, varscan2
- TRAK1 | c.1744+36C>T | Intron (SNP) | VAF 16/60 reads (27%) | called by muse, mutect2, varscan2
- TUBA4A | c.-33G>A | 5'UTR (SNP) | VAF 4/21 reads (19%) | catalogued as rs559586186; called by muse, mutect2, varscan2
